Somatic mutation profile of tumor specimen MP2PRT-PASPWX-TMP1-A (aliquot MP2PRT-PASPWX-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASPWX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,141 days).
Specimen MP2PRT-PASPWX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4416fb0-246b-47b2-9fc1-626a28931d86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASPWX-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASPWX-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78fb128b-6eef-42e1-bce4-a5aebe2ee372

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CHGB | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 157/387 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs369985726; called by muse, mutect2, varscan2
- SGCZ | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372855106; called by muse, mutect2, varscan2
- SHANK2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs528418101, COSV58341843; called by muse, mutect2, varscan2
- FBXO25 | c.206A>G p.K69R (on ENST00000382824 / NM_183421.2; = p.R19G on NM_012173.3) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); called by muse, varscan2
- IRS2 | c.2206T>A p.S736T | Missense Mutation (SNP) | VAF 302/774 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2
- SFTPD | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- CNTLN | c.2142G>A p.G714= | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, varscan2
- KCNQ1 | c.1394-18405C>T | Intron (SNP) | VAF 24/117 reads (21%) | catalogued as rs1473364577; called by muse, mutect2, varscan2
